TCGA case TCGA-F5-6702 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f1ce4b5f-55d0-4989-a5f3-6b6e591538b2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 71 years; Vital status: Dead; Days to death: 869 days (2.4 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 71.5 years (26,123 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 869 days (2.4 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 12; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 340 days; Days to treatment end: 551 days (1.5 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 370 days (1.0 years); Days to treatment end: 641 days (1.8 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 370 days (1.0 years); Days to treatment end: 641 days (1.8 years); Treatment outcome: Progressive Disease; Drug category: Platinum.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.5 years (26,491 days); Days to diagnosis: 368 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (4 entries)
- Days to follow up: 66 days; Disease response: With Tumor.
- Day 368 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 452 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 869 days (2.4 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 172 cm; BMI: 25.7.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F5-6702-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.8; Intermediate dimension: 1.5; Shortest dimension: 0.8.
  Slide TCGA-F5-6702-01A-01-BS1: Section location: Bottom; Percent tumor cells: 78; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 2; Percent stromal cells: 15.
  Slide TCGA-F5-6702-01A-01-TS1: Section location: Top; Percent tumor cells: 74; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 1; Percent stromal cells: 20.
- Sample TCGA-F5-6702-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F5-6702-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Rectum; Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; Colon polyps at procurement indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-Fluorouracil; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Polyplatillen; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 452 days; disease-specific survival: no event (censored), 452 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 368 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F5-6702-01A-11D-1825-01): tumor purity 0.33, ploidy 3.68, whole-genome doublings 1.
